Somatic mutation profile of tumor specimen MMRF_1085_3_BM_CD138pos (aliquot MMRF_1085_3_BM_CD138pos_T1_KBS5U_L05831) from MMRF case MMRF_1085, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.6 years (22,137 days).
Specimen MMRF_1085_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee8b3e54-a49a-4063-81c3-4afc5b4ef8c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1085_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1085_2_PB_Whole_C1_KBS5U_L05763; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ff6cc33-e0ab-48b1-ad32-00602c81133e

The open-access MAF lists 86 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 18, Intron 11, Silent 9, 5'Flank 6, 3'Flank 5, RNA 4, Nonsense Mutation 3, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRB2 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV60005320; called by muse, mutect2, varscan2
- CACNB2 | c.1858G>A p.E620K (on ENST00000324631 / NM_201596.3; = p.E565K on NM_000724.4) | Missense Mutation (SNP) | VAF 101/107 reads (94%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.218); catalogued as rs761643494, COSV56638507; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD163 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 130/288 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs751233497, COSV63132083; called by muse, mutect2, varscan2
- DSCAM | c.5780C>T p.A1927V | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); catalogued as rs1436235793; called by muse, mutect2, varscan2
- GPRIN1 | c.2197G>A p.G733S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs749373471; called by muse, mutect2, varscan2
- IGHV3-33 | c.279T>A p.N93K | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as rs528876839; called by muse, varscan2
- IGHV3-33 | c.140C>G p.T47S | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs187304239; called by muse, varscan2
- IGLV3-1 | c.286A>C p.T96P | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs774168565; called by muse, varscan2
- ITGAV | c.2251A>G p.N751D | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447097348; called by muse, mutect2, varscan2
- MFHAS1 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 46/47 reads (98%) | catalogued as COSV99359550; called by muse, mutect2, varscan2
- NUCB1 | c.867G>C p.M289I | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54387947; called by muse, mutect2, varscan2
- PTPN13 | c.5422C>A p.Q1808K (on ENST00000411767 / NM_080683.3; = p.Q1789K on NM_006264.3) | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.173); catalogued as COSV57411018; called by muse, mutect2, varscan2
- RIMS2 | c.1523G>A p.R508H (on ENST00000666250 / NM_001348490.2; = p.R316H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/159 reads (58%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV51669990; called by muse, mutect2, varscan2
- TSKS | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs997208348; called by muse, mutect2, varscan2
- TXNIP | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100997262; called by muse, mutect2, varscan2
- ABCC1 | c.928A>G p.N310D | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANXA1 | c.822A>C p.K274N | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- DLD | c.383G>C p.S128T | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENKUR | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HTRA1 | c.755C>A p.A252E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- METTL23 | c.206A>T p.N69I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MORF4L1 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 135/533 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PWWP2B | c.1499G>A p.G500D | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RHOBTB1 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- SBK1 | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SLC15A3 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCA2 | c.2736G>T p.W912C | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNRPB | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCTE1 | c.723_731del p.E241_L243del | In Frame Del (DEL) | VAF 35/87 reads (40%) | called by mutect2, pindel, varscan2
- TTN | c.60722G>C p.C20241S (on ENST00000591111; = p.C12817S on NM_003319.4) | Missense Mutation (SNP) | VAF 50/122 reads (41%) | PolyPhen benign (0.001); called by muse, mutect2
- ZEB1 | c.776T>A p.L259* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- ZNF300 | c.1650A>G p.I550M | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADAMTS10 | c.1623G>A p.S541= | Silent (SNP) | VAF 43/66 reads (65%) | catalogued as COSV54353331; called by muse, mutect2, varscan2
- BHLHE41 | c.1056C>T p.C352= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs774486513, COSV54378544; called by muse, mutect2, varscan2
- FREM2 | c.8823C>T p.A2941= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs1221414972; called by muse, mutect2, varscan2
- HDAC11 | c.276C>T p.I92= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as COSV99849947; called by muse, mutect2, varscan2
- NCOR2 | c.693C>T p.Y231= | Silent (SNP) | VAF 56/110 reads (51%) | catalogued as rs761420828; called by muse, mutect2, varscan2
- ORAI2 | c.475C>T p.L159= | Silent (SNP) | VAF 94/199 reads (47%) | called by muse, mutect2, varscan2
- PRX | c.1287G>T p.V429= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as COSV52528523; called by muse, mutect2, varscan2
- UBQLNL | c.600C>T p.D200= | Silent (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- ZFYVE9 | c.630G>A p.E210= | Silent (SNP) | VAF 60/140 reads (43%) | catalogued as COSV55100917; called by muse, mutect2, varscan2
- AGO1 | c.*1756G>T | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- AP000769.5 | chr11:65499834 C>T | 5'Flank (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- ATE1 | c.*2810C>T | 3'UTR (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- ATP6AP1L | n.1450C>T | RNA (SNP) | VAF 56/104 reads (54%) | catalogued as rs752305384; called by muse, mutect2, varscan2
- C14orf177 | n.605G>A | RNA (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- CALN1 | c.*1727G>T | 3'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- CAMK4 | c.*4635dup | 3'UTR (INS) | VAF 24/60 reads (40%) | called by mutect2, varscan2
- CFAP20DC | c.1593+2005T>G | Intron (SNP) | VAF 37/132 reads (28%) | called by muse, mutect2, varscan2
- CLK4 | c.161+641T>G | Intron (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- DPM2 | c.93+21G>A | Intron (SNP) | VAF 95/145 reads (66%) | catalogued as rs770273949; called by muse, mutect2, varscan2
- FAM133A | c.*921G>T | 3'UTR (SNP) | VAF 23/64 reads (36%) | catalogued as COSV59074583; called by muse, mutect2, varscan2
- FLRT3 | c.*1461A>G | 3'UTR (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2, varscan2
- FOXP2 | c.*1629A>T | 3'UTR (SNP) | VAF 47/84 reads (56%) | called by muse, mutect2, varscan2
- FREM2 | c.*1639T>A | 3'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- GDI2 | c.-122A>G | 5'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- GID4 | c.*1904G>A | 3'UTR (SNP) | VAF 3/44 reads (7%) | catalogued as rs1368332603; called by muse, mutect2
- IFIT5 | c.*270A>T | 3'UTR (SNP) | VAF 45/89 reads (51%) | called by muse, mutect2, varscan2
- IGSF23 | c.125+4410G>A | Intron (SNP) | VAF 24/53 reads (45%) | catalogued as rs555582631; called by muse, mutect2, varscan2
- IL16 | chr15:81312064 A>G | 3'Flank (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- IQCJ | chr3:159265945 T>G | 3'Flank (SNP) | VAF 46/67 reads (69%) | called by muse, mutect2, varscan2
- KRT18P23 | chr22:44572161 G>A | 3'Flank (SNP) | VAF 15/32 reads (47%) | catalogued as rs373132789; called by muse, mutect2, varscan2
- LAT | chr16:28985056 C>T | 5'Flank (SNP) | VAF 14/20 reads (70%) | catalogued as rs543635052; called by muse, mutect2, varscan2
- LRCH1 | c.*1472C>A | 3'UTR (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- LTB | c.163-151T>A | Intron (SNP) | VAF 70/140 reads (50%) | called by muse, mutect2, varscan2
- MAPK8IP1P2 | n.122G>A | RNA (SNP) | VAF 16/74 reads (22%) | catalogued as rs1291114098; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851238 C>G | 5'Flank (SNP) | VAF 61/148 reads (41%) | catalogued as rs550463544; called by muse, mutect2, varscan2
- MXD1 | c.173+58G>A | Intron (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2
- NTRK3 | chr15:87872927 C>T | 3'Flank (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- OVCH1-AS1 | n.318C>T | RNA (SNP) | VAF 19/36 reads (53%) | catalogued as rs779906318; called by muse, mutect2, varscan2
- PCDH11X | c.3033+277del | Intron (DEL) | VAF 221/297 reads (74%) | called by mutect2, pindel, varscan2
- PPM1L | chr3:160755940 del C | 5'Flank (DEL) | VAF 38/144 reads (26%) | called by mutect2, pindel, varscan2
- PRG2 | c.367-32C>T | Intron (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- RRP8 | c.*529C>T | 3'UTR (SNP) | VAF 33/108 reads (31%) | called by muse, mutect2, varscan2
- RUNX1 | chr21:34889686 G>A | 5'Flank (SNP) | VAF 5/10 reads (50%) | called by muse, varscan2
- SBK1 | c.*330G>T | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- SHANK2 | c.*2682G>C | 3'UTR (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143624107 C>A | 3'Flank (SNP) | VAF 88/90 reads (98%) | called by muse, varscan2
- SMC4 | c.687+92T>G | Intron (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- SRCAP | c.5658+44T>G | Intron (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- STK11IP | c.*182G>A | 3'UTR (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- SYBU | c.*871C>T | 3'UTR (SNP) | VAF 47/121 reads (39%) | called by muse, mutect2, varscan2
- TMEM154 | c.*9126G>A | 3'UTR (SNP) | VAF 69/115 reads (60%) | called by muse, mutect2, varscan2
- TMEM59 | chr1:54053412 C>T | 5'Flank (SNP) | VAF 24/52 reads (46%) | catalogued as rs1179443094; called by muse, mutect2, varscan2
- ZNF696 | c.*857T>A | 3'UTR (SNP) | VAF 6/60 reads (10%) | catalogued as rs1485705575; called by muse, mutect2
- ZSCAN32 | c.872-24G>A | Intron (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
